Surgical pathology report (de-identified scan), TCGA case TCGA-AA-A010, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-A010-01A (Primary Tumor).

ICD-0-3
Adenocarcinoma, NOS 8140/3
Site: transverse colon C18.4 for 3/29/11

Sample ID #:

Diagnosis:

- 1.: Tumor-free lymph node (from the mesenteric root).
- 2.: Resectate of the transverse colon with tumor-free oral and aboral resection margins and under inclusion of a locally advanced, ulcerated, poorly differentiated adenocarcinoma with penetration of all layers of the wall, with infiltration of the perimuscular fatty tissue and the neighboring omentum, with invasion of the stomach wall and without regional lymph node metastases (G3, pT4 L0 V0 R0 pN0 0/45).
- 3.: Tumor-free spleen with fresh (iatrogenic) defects to the capsule.

As requested, a paraffin block of the material was sent to Prof. for further analyses to exclude or demonstrate the presence of an HNPCC situation. A follow-up report on this will be submitted at a later date.

Follow-up report:

Based on the findings described in the enclosed copy of the consultation report that has now arrived, Prof. (Pathology, finds no further indications of the presence of an hereditary predisposition to the spectrum of tumors within the HNPCC / Lynch Syndrome.

Source: NCI Genomic Data Commons file d2a7700a-e7d4-493e-a5f7-619b82971d89 (TCGA-AA-A010.7C26217F-5005-4D0F-9E8A-01E31908AB01.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).